Surgical pathology report (de-identified scan), TCGA case TCGA-24-1423, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1423-01A (Primary Tumor).

[page 1 of 4]
FINAL

DIAGNOSIS:

OMENTUM, OMENTECTOMY (INCLUDING FS1)

- METASTATIC ADENOCARCINOMA (SEE COMMENT)

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA WITH FOCAL ENDOMETRIOID DIFFERENTIATION (SEE COMMENT)
- ADENOCARCINOMA INVADES THE MYOMETRIUM TO A DEPTH OF 3 MM OUT OF 15 MM
- LYMPHOVASCULAR INVASION IS IDENTIFIED

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- ADENOCARCINOMA BY DIRECT EXTENSION
- LEIOMYOMATA, UP TO 4.5 CM

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- ADENOCARCINOMA INVOLVING THE MUCOSA AND STROMA

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- ADENOCARCINOMA WITH SURFACE INVOLVEMENT

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- INTRALUMINAL ADENOCARCINOMA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- MIXED HIGH GRADE SEROUS AND ENDOMETRIOID CARCINOMAS WITH SURFACE INVOLVEMENT

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA IN PERITUBAL SOFT TISSUE

APPENDIX, APPENDECTOMY

- METASTATIC ADENOCARCINOMA
- NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

RECTOSIGMOID NODULE, EXCISION

- METASTATIC ADENOCARCINOMA

GASTROCOLIC OMENTUM, EXCISION

- METASTATIC ADENOCARCINOMA

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

RIGHT DIAPHRAGM, NODULES, EXCISION
- METASTATIC ADENOCARCINOMA

FALCIFORM LIGAMENT, BIOPSY
- NO CARCINOMA IDENTIFIED

RIGHT DIAPHRAGM, NODULE #2, EXCISION
- METASTATIC ADENOCARCINOMA

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'omentum' is a 64 gram fragment of fibrofatty tissue measuring 13 x 8 x 4 cm. Sectioning reveals ill-defined firm areas with gray-white gritty cut surfaces. A portion is frozen as FS1. Rest for permanents," by [REDACTED]

FS1 with touch prep 1: Omentum, biopsy

Microscopic Description and Comment:

Sections of the endometrium, left ovary and omentum show mixed high grade serous carcinoma and endometrioid carcinoma (overall about 60% endometrioid and 40% serous). There is also high grade serous carcinoma in the cervix, right ovary, peritubal soft tissue of the left fallopian tube and detached intraluminal fragments of high grade serous carcinoma within the right fallopian tube. Within the endometrium, the carcinoma invades the myometrium and extends to the cervical mucosa with stromal invasion.

Whenever there is carcinoma in the ovaries and endometrium, it can be difficult or impossible to decide whether these represent synchronous primary tumors or whether one site represents metastatic spread from another site. In this case, factors that favor an endometrial primary with metastases to ovary and peritoneum include the presence of an identical mixed serous and endometrioid morphology in both locations as well as myometrial invasion, lymphovascular space invasion and cervical extension in the uterus. However, clinical correlation is recommended to arrive at a final determination.

History:

The patient is a [REDACTED] who has an adnexal mass and an elevated CA125. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, and optimal tumor debulking.

Specimen(s) Received:

A: OMENTUM

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

B: CERVIX, UTERUS, BILATERAL TUBES AND OVARIES
C: APPENDIX
D: RECTO-SIGMOID NODULES
E: OMENTUM (GASTROCOLIC)
F: RIGHT DIAPHRAGM NODULES
G: FALCIFORM LIGAMENT
H: RIGHT DIAPHRAGM NODULE #2

Gross Description:

The specimens are received in eight formalin-filled containers, each labeled [REDACTED]. The first container is labeled "omental biopsy, FS1/X." It contains a white cassette that holds a portion of yellow-tan tissue measuring 2.2 x 2.2 x 0.2 cm. Additionally in the container is a 13 x 8 x 4 cm portion of yellow omentum. Sections show a diffusely firm yellow-tan cut surface with innumerable tan tumor nodules measuring up to 2 cm. Labeled A1 - remnant of FS1; A2 - section including largest tumor nodule. [REDACTED]

The second container is labeled "cervix, uterus, bilateral tubes and ovaries." It contains a 223-gram uterus, cervix, and attached right adnexa. The uterus measures 9.5 cm inferior-to-superior; 8 cm cornu-to-cornu; and 4.5 cm anterior-to-posterior. The uterine serosa is tan and smooth. The 3.3 x 3 cm ectocervix is partially disrupted anteriorly and has a tan-brown slightly rough surface with pinpoint hemorrhages. The 2.8 cm endocervix is tan, unremarkable, and patent. The 3.5 x 3 cm endometrial cavity is distorted by fibroids and has a tan, unremarkable surface with a thickness of 0.1 cm. The myometrium contains numerous fibroids, the largest of which measures 4.5 x 4 x 3.8 cm and is in the right anterolateral aspect of the fundus. There is a fibroid in the posterior wall that is extensively calcified. All of the fibroids have well-circumscribed and tan-white whorled cut surfaces without hemorrhage or necrosis. The non-fibroid myometrial wall thickness measures 2 cm. The right adnexa measures 5 x 4.5 x 3 cm and has a rough, tan surface with scattered tumor nodules. Sections show a tan cut surface that is partially replaced by tan, papillary, friable tumor. The 6 x 0.8 cm fallopian tube has a tan smooth serosal surface and is sectioned to show a tan-brown cut surface with focal hemorrhage and a pinpoint lumen. Additionally in the container is a left adnexa weighing 26 grams. The ovary is distorted by enumerable, tan, focally papillary tumor covering most of the surface. At one end there appears to be a disrupted cyst wall. The ovary/mass measures 7 x 3 x 2.8 cm. Sections show a solid and cyst mass. Some of the cysts have yellow gelatinous material. The solid areas are tan with more papillary areas on the surface. The adherent fallopian tube measures 4 x 1 cm and has a tan smooth serosa with a tan cut surface and a pinpoint lumen. Acid decalcification. Labeled B1 to B3 contiguous anterior strip with B1 containing cervix, B2 containing lower uterine segment, and B3 containing endometrium; B4 to B6 contiguous posterior strip with B4 containing cervix, B5 containing lower uterine segment, and B6 containing endometrium with calcified underlying leiomyoma; B7 to B9 - right ovary with B7 containing surface tumor; B10 - right fallopian tube; B11 to B14 - left ovary; B15 - left fallopian tube; B16 to B19 - remainder of posterior endometrium; B20 to B27 - remainder of anterior endometrium with B20 to B25 containing a surface papillary area. [REDACTED]

The third container is labeled "appendix". It contains a 4.5 x 1 x 0.8 cm appendix with a tan serosal surface that is less hemorrhagic and has numerous tan nodules on the surface measuring up to 0.3 cm. There is up to 1 x 1 cm of tan-yellow mesoappendix. Sections show a tan cut surface with a wall thickness of up to 0.4 cm and as thin as 0.1 cm. The lumen is obliterated towards the tip. Proximally the lumen is filled with white mucoid material and has a diameter of 0.5 cm. Labeled C1 to C2 - tip with tumor; C3 - proximal appendix with mucoid material; C4 - margin. Jar 1.

The fourth container is labeled "rectosigmoid nodule." It contains numerous fragments of tan and brown tumor measuring in aggregate 2.5 x 2 x 0.7 cm. Sectioned. Labeled D1. [REDACTED]

The fifth container is labeled "omentum/gastrocolic." It contains three pieces of yellow-tan omentum measuring 25 x 6.5 x 0.9 cm; 18 x 3.5 x up to 1.6 cm; and 17 x 6 x 1 cm. The second piece contains a large tan tumor nodule measuring 2.1 cm. Sectioned to show a few smaller tan tumor nodules measuring up to 0.3 cm. Labeled E1 - largest tumor nodule and a smaller tumor nodule. [REDACTED]

The sixth container is labeled "right diaphragm nodule." It contains multiple fragments of tan tissue measuring in aggregate 1.6 x 1.1 x 0.3 cm. Wrapped. Labeled F1. [REDACTED]

The seventh container is labeled "falciform ligament." It contains a portion of yellow-brown soft tissue measuring 10.8 x 6.7 x 1.2 cm. The surface is tan, smooth, and glistening. Sectioned to show tan and red hemorrhagic tissue. No definite gross tumor nodules are seen. A putative tan, unremarkable lymph node is identified measuring 0.7 cm. Labeled G1 - putative lymph node; G2 - hemorrhagic soft tissue; G3 - unremarkable soft tissue. [REDACTED]

The eighth container is labeled "right diaphragm nodule #2, rule out pleural invasion." It contains multiple fragments of

[page 4 of 4]
[illegible]

Source: NCI Genomic Data Commons file 5c713b04-ae78-4607-a9c6-515b241061f8 (TCGA-24-1423.47331163-68E9-44FD-8B80-B9F70058957F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).